CCDI case PBCPJT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/d559ac2f-2192-410e-9555-02f8948067b6

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 15.0 years (5,471 days).

Biospecimens (3 samples)
- Sample 0DX7EO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DX7F2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DX7FK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
